Somatic mutation profile of tumor specimen TCGA-A4-7286-01A (aliquot TCGA-A4-7286-01A-11D-2136-08) from TCGA case TCGA-A4-7286, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 42.8 years (15,631 days).
Specimen TCGA-A4-7286-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d9fd4d5-8c7b-424f-9a4c-177c0773d501.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7286-10A (Blood Derived Normal), aliquot TCGA-A4-7286-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a30e06db-aff5-4409-9aa0-41cfd2942cf8

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Silent 7, Frame Shift Del 4, Nonsense Mutation 1, Splice Site 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L2 | c.2187T>G p.I729M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51557075; called by muse, mutect2, varscan2
- ALDH3A2 | c.1357T>A p.F453I | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV51567303; called by muse, mutect2, varscan2
- ANKS6 | c.1891T>A p.F631I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV62050835; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.935G>C p.C312S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63438274; called by muse, mutect2, varscan2
- ATP10A | c.1777-1G>C p.X593_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV63519261; called by muse, mutect2, varscan2
- CCKBR | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.11); catalogued as COSV58102600; called by muse, mutect2, varscan2
- CCNG2 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs1318529475, COSV60354050; called by muse, mutect2, varscan2
- CHD6 | c.3467G>C p.W1156S | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58558785; called by muse, mutect2, varscan2
- COL22A1 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV57322310, COSV57343561; called by muse, mutect2, varscan2
- DDX56 | c.1409A>C p.D470A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51836960; called by muse, mutect2, varscan2
- DOCK1 | c.5393T>A p.V1798D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as COSV54745639; called by muse, mutect2, varscan2
- ENGASE | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.505); catalogued as COSV56136240, COSV56137880; called by muse, mutect2, varscan2
- EPS8 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV55532705; called by muse, mutect2, varscan2
- FTMT | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as rs756710919, COSV58420216; called by muse, mutect2, varscan2
- GPATCH11 | c.543A>C p.E181D (on ENST00000409774; = p.E159D on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV56135502; called by muse, mutect2, varscan2
- GPATCH11 | c.544A>T p.M182L (on ENST00000409774; = p.M160L on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56135523; called by muse, mutect2, varscan2
- HM13 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59437767; called by muse, mutect2, varscan2
- KAT14 | c.1069C>G p.P357A | Missense Mutation (SNP) | VAF 119/582 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66608183; called by muse, mutect2, varscan2
- KYNU | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51582328, COSV51585968; called by muse, mutect2, varscan2
- LRP4 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV66136625; called by muse, mutect2, varscan2
- LY75 | c.4778A>G p.N1593S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.574); catalogued as COSV55107930; called by muse, mutect2, varscan2
- PARD6B | c.1117T>C p.*373Rext*13 | Nonstop Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV65404678; called by muse, mutect2, varscan2
- PROCA1 | c.78+8G>A | Splice Region (SNP) | VAF 10/78 reads (13%) | catalogued as rs768637282, COSV99973043; called by muse, mutect2, varscan2
- PRSS55 | c.542C>G p.P181R | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.091); catalogued as COSV60808622, COSV99073619; called by muse, mutect2, varscan2
- RNF6 | c.1687A>T p.S563C | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV60419393; called by muse, mutect2, varscan2
- RTKN | c.526T>C p.F176L (on ENST00000272430 / NM_001015055.2; = p.F163L on NM_033046.2) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51964390; called by muse, mutect2, varscan2
- SCAF11 | c.3274C>A p.Q1092K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV65477343; called by muse, mutect2, varscan2
- SYNPO2 | c.2776A>T p.N926Y | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61113168; called by muse, mutect2, varscan2
- TEP1 | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as COSV52994767; called by muse, mutect2, varscan2
- FBXL19 | c.816del p.C273Afs*35 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- FKBP9 | c.456del p.Y153Ifs*17 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- MORN3 | c.37del p.L13Cfs*21 | Frame Shift Del (DEL) | VAF 40/228 reads (18%) | called by mutect2, pindel, varscan2
- SLC17A6 | c.125_126del p.E42Afs*149 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- AATK | c.2784T>A p.S928= (on ENST00000326724 / NM_001080395.3; = p.S825= on NM_004920.2) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV58368850; called by muse, mutect2, varscan2
- ALG2 | c.693C>T p.I231= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV53060144; called by muse, mutect2, varscan2
- INHBC | c.81A>C p.P27= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV59005509; called by muse, mutect2, varscan2
- NCOA1 | c.4225C>T p.L1409= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV56047205; called by muse, mutect2, varscan2
- PRPF6 | c.1623T>C p.H541= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV53872934; called by muse, mutect2, varscan2
- SPOPL | c.300A>G p.A100= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV54514273; called by muse, mutect2, varscan2
- TRIM52 | c.732C>A p.A244= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV59844300, COSV59844494; called by muse, mutect2, varscan2
